Gene-level copy-number profile of tumor specimen TCGA-A6-6654-01A from TCGA case TCGA-A6-6654, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.6 years (23,953 days).
Specimen TCGA-A6-6654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.1d415193-fcd9-4b98-afee-cb3f02f197b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6654-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/616d66c4-7bfc-4476-a18d-1fbb7d5c40b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,570; copy number 2: 26,929; copy number 3: 16,954; copy number 4: 11,375; copy number 5: 1,847; copy number 6: 51; copy number 7: 121; copy number 8: 916; copy number 12: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6654-01A-21D-1834-01): tumor purity 0.32, ploidy 2.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,954 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:192,629,919–210,315,174, 333 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:6,952,625–19,146,253, 136 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:18,467,172–53,052,057, 708 genes, copy number 5 (broad region; genes not listed).
- chr13:54,572,354–114,337,626, 670 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:87,250–4,249,287, 140 genes, copy number 7–12 (broad region; genes not listed).
- chr20:9,505,180–10,387,806, 17 genes, copy number 8: LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2.
- chr20:19,000,709–21,755,350, 51 genes, copy number 6 (within-gene range 3–6): AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1.
- chr20:30,214,765–64,313,132, 899 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
